Somatic mutation profile of tumor specimen ALCH-B1ZE-TTP1-A (aliquot ALCH-B1ZE-TTP1-A-3-0-D-A76I-36) from ALCHEMIST case ALCH-B1ZE, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 68.3 years (24,958 days).
Specimen ALCH-B1ZE-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a8181a10-bb1e-4f3e-96a2-8fd975569457.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1ZE-NB1-A (Blood Derived Normal), aliquot ALCH-B1ZE-NB1-A-1-0-D-A76I-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2a4ae183-f230-4b68-8b87-6c9572f05add

The open-access MAF lists 320 somatic variants for this specimen: 203 protein-altering or splice-affecting, 63 silent, 54 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 179, Silent 63, Intron 34, Nonsense Mutation 14, 5'UTR 8, RNA 7, 3'UTR 3, Frame Shift Del 3, Splice Site 3, Frame Shift Ins 2, Splice Region 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 106/179 reads (59%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.830G>T p.C277F | Missense Mutation (SNP) | VAF 88/164 reads (54%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs763098116, CM078491, COSV52693726, COSV52826087, COSV53107923; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCC3 | c.2156G>C p.R719P | Missense Mutation (SNP) | VAF 83/176 reads (47%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.899); catalogued as COSV99559515; called by muse, mutect2, varscan2
- ACTG2 | c.22G>A p.A8T | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.887); catalogued as rs1242882385, COSV100609152; called by muse, mutect2, varscan2
- ACVRL1 | c.452G>A p.R151H | Missense Mutation (SNP) | VAF 93/207 reads (45%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs571039541, COSV66360074; called by muse, mutect2, varscan2
- ADCK5 | c.193C>T p.R65C | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.033); catalogued as rs782782811, COSV100450557; called by muse, mutect2, varscan2
- ADGRF4 | c.2077C>G p.R693G | Missense Mutation (SNP) | VAF 49/124 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.212); catalogued as COSV51949975; called by muse, mutect2, varscan2
- ADORA1 | c.461G>T p.R154L | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV99704302; called by muse, mutect2, varscan2
- AHCTF1 | c.3577A>G p.K1193E (on ENST00000366508; = p.K1167E on NM_015446.5) | Missense Mutation (SNP) | VAF 37/350 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.163); catalogued as COSV58254135; called by muse, mutect2, varscan2
- ANKK1 | c.2275C>A p.P759T | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.031); catalogued as COSV100392785; called by muse, mutect2
- ATP10A | c.1988C>T p.S663L | Missense Mutation (SNP) | VAF 35/147 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.017); catalogued as rs777246990; called by muse, mutect2, varscan2
- C6 | c.322C>T p.R108C | Missense Mutation (SNP) | VAF 17/148 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs530594382, COSV54711721; called by muse, mutect2, varscan2
- CACNA1A | c.6947G>A p.G2316E | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT tolerated (0.49); PolyPhen benign (0.236); catalogued as rs1454085231; called by muse, mutect2, varscan2
- CACNA1B | c.5536C>A p.P1846T | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.29); catalogued as COSV53121016, COSV99498448; called by muse, mutect2, varscan2
- CBLIF | c.552C>A p.Y184* | Nonsense Mutation (SNP) | VAF 53/136 reads (39%) | catalogued as rs1387305169; called by muse, mutect2, varscan2
- CCDC85A | c.760G>T p.A254S | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0.011); catalogued as rs554353955, COSV68151378; called by muse, mutect2, varscan2
- CDH4 | c.679G>A p.G227S | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs767509293; called by muse, mutect2, varscan2
- CEP135 | c.1746G>T p.M582I | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV99954810; called by muse, mutect2, varscan2
- CEP63 | c.1415A>G p.E472G | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs1195032646; called by mutect2, varscan2
- CILP2 | c.1414C>T p.R472W | Missense Mutation (SNP) | VAF 38/118 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs1227767281, COSV52273218; called by muse, mutect2, varscan2
- COL20A1 | c.3373C>A p.P1125T | Missense Mutation (SNP) | VAF 43/106 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs753259352, COSV58929272; called by muse, mutect2, varscan2
- CSMD2 | c.2240G>A p.R747Q | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs771665223, COSV99594667; called by muse, mutect2, varscan2
- CTLA4 | c.386G>T p.C129F | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99865469; called by muse, mutect2, varscan2
- CYP46A1 | c.235G>A p.V79I | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT tolerated (0.52); PolyPhen benign (0.058); catalogued as rs752350612, COSV55897263; called by muse, mutect2, varscan2
- DYNC1I1 | c.161G>A p.R54H | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.629); catalogued as rs377495263; called by muse, mutect2, varscan2
- ERICH3 | c.2854G>T p.D952Y | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV100443933; called by muse, mutect2, varscan2
- FER1L5 | c.3475C>T p.L1159F (on ENST00000623019; = p.L1132F on NM_001293083.2) | Missense Mutation (SNP) | VAF 25/105 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1051836882; called by muse, mutect2, varscan2
- FMN2 | c.4450G>A p.G1484S | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT tolerated (0.43); PolyPhen benign (0.19); catalogued as COSV60447313; called by muse, varscan2
- FOXB2 | c.839A>G p.Y280C | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.298); catalogued as rs764363098; called by muse, mutect2, varscan2
- FSIP2 | c.805G>T p.D269Y | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV58099451; called by muse, mutect2, varscan2
- GLDC | c.164G>T p.R55L | Missense Mutation (SNP) | VAF 15/168 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs1195896229; called by muse, mutect2
- ICA1 | c.931C>T p.R311C | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs570072277, COSV55583956; called by mutect2, varscan2
- IMPDH1 | c.688C>T p.R230* (on ENST00000470772 / NM_001142573.2; = p.R316* on NM_000883.4) | Nonsense Mutation (SNP) | VAF 6/48 reads (13%) | catalogued as rs1282816133, COSV58315119; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- INTS13 | c.1324G>C p.E442Q | Missense Mutation (SNP) | VAF 24/168 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.099); catalogued as COSV53905210, COSV99677044; called by muse, mutect2, varscan2
- IRS4 | c.2100C>G p.Y700* | Nonsense Mutation (SNP) | VAF 4/14 reads (29%) | catalogued as COSV64534015; called by muse, mutect2
- ITSN1 | c.1144C>T p.R382C | Missense Mutation (SNP) | VAF 112/535 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs764739038, COSV66083016; called by muse, mutect2, varscan2
- JKAMP | c.769G>A p.D257N (on ENST00000554271 / NM_001284201.1; = p.D243N on NM_016475.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV54198794; called by muse, varscan2
- JMJD1C | c.815C>T p.A272V | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs1463435908; called by mutect2, varscan2
- JRK | c.1556G>T p.R519L | Missense Mutation (SNP) | VAF 61/191 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.129); catalogued as rs781958857; called by muse, mutect2, varscan2
- LAMA1 | c.313C>T p.H105Y | Missense Mutation (SNP) | VAF 61/222 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101057279; called by muse, mutect2, varscan2
- LRP1B | c.13095dup p.G4366Wfs*8 | Frame Shift Ins (INS) | VAF 25/184 reads (14%) | catalogued as COSV101260871; called by mutect2, pindel, varscan2
- LRP2 | c.1141C>A p.R381S | Missense Mutation (SNP) | VAF 50/144 reads (35%) | SIFT tolerated (0.4); PolyPhen benign (0.027); catalogued as COSV99788358; called by muse, mutect2, varscan2
- MDH1B | c.622del p.A208Pfs*35 | Frame Shift Del (DEL) | VAF 17/55 reads (31%) | catalogued as COSV65589025, COSV65589622; called by mutect2, pindel, varscan2
- MOCOS | c.1586T>C p.L529P | Missense Mutation (SNP) | VAF 37/95 reads (39%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs376541030; called by muse, mutect2, varscan2
- MUC1 | c.2804C>T p.P935L (on ENST00000611571 / NM_001371720.1; = p.P148L on NM_001204285.2) | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT tolerated (0.55); PolyPhen benign (0.029); catalogued as rs534391658, COSV58116184; called by muse, mutect2
- MUC5B | c.10199C>A p.T3400N | Missense Mutation (SNP) | VAF 45/365 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.014); catalogued as rs772186309; called by muse, mutect2, varscan2
- MYH4 | c.2372G>C p.R791P | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.259); catalogued as COSV55111888, COSV55125528; called by muse, mutect2, varscan2
- NANOGNB | c.557C>A p.A186D | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); catalogued as COSV66125197; called by muse, varscan2
- NPY5R | c.641C>A p.S214Y | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.793); catalogued as COSV58450928, COSV58451496; called by muse, mutect2, varscan2
- NRK | c.2578A>G p.T860A | Missense Mutation (SNP) | VAF 42/61 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs985585075; called by muse, mutect2, varscan2
- OR10A3 | c.860C>T p.P287L | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.043); catalogued as rs140281755; called by muse, mutect2, varscan2
- OR51G2 | c.875T>C p.M292T | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.193); catalogued as rs762223257; called by mutect2, varscan2
- OR6C1 | c.379C>A p.P127T | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.946); catalogued as rs1303519176, COSV101110461; called by muse, mutect2, varscan2
- OSBP | c.1540C>T p.R514* | Nonsense Mutation (SNP) | VAF 33/69 reads (48%) | catalogued as COSV55660996; called by muse, varscan2
- PIP4K2A | c.769G>T p.E257* | Nonsense Mutation (SNP) | VAF 33/196 reads (17%) | catalogued as COSV100114470; called by muse, mutect2, varscan2
- PLXNA4 | c.2663G>A p.R888H | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.425); catalogued as rs751969293, COSV58122840; called by muse, mutect2, varscan2
- POTEE | c.2759C>G p.A920G | Missense Mutation (SNP) | VAF 80/674 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.078); catalogued as COSV100388222; called by muse, varscan2
- PRR5-ARHGAP8 | c.710C>T p.A237V (on ENST00000352766; = p.A114V on NM_181334.5) | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs747124155, COSV61231320; called by muse, mutect2, varscan2
- RAB40A | c.710G>A p.R237Q | Missense Mutation (SNP) | VAF 36/175 reads (21%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as rs1221413109, COSV58491738; called by muse, mutect2, varscan2
- RCVRN | c.265G>A p.A89T | Missense Mutation (SNP) | VAF 41/161 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs568278385, COSV56841007; called by muse, mutect2, varscan2
- RELCH | c.577T>C p.S193P | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1234209834; called by muse, mutect2, varscan2
- RYR2 | c.9466G>A p.G3156R | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749825473; called by muse, mutect2, varscan2
- SGCE | c.107C>G p.T36R | Missense Mutation (SNP) | VAF 85/186 reads (46%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.998); catalogued as CM081435; called by muse, mutect2, varscan2
- SLC25A48 | c.526G>T p.G176W (on ENST00000650267; = p.G122W on NM_001349335.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV50850676; called by muse, mutect2, varscan2
- SMYD3 | c.1160C>G p.P387R (on ENST00000490107 / NM_001375962.1; = p.P328R on NM_022743.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/130 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.017); catalogued as COSV63626270; called by muse, mutect2, varscan2
- SPTA1 | c.5293C>A p.H1765N | Missense Mutation (SNP) | VAF 18/175 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63757247; called by muse, mutect2
- SRRM5 | c.1567C>T p.R523* | Nonsense Mutation (SNP) | VAF 27/233 reads (12%) | catalogued as rs756714810; called by muse, mutect2, varscan2
- SYT12 | c.956C>T p.A319V | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.86); catalogued as rs201262067; called by muse, mutect2, varscan2
- TEC | c.1083G>T p.E361D | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.006); catalogued as rs1168086018, COSV67403418, COSV67406129; called by muse, mutect2, varscan2
- TMPRSS11F | c.638C>A p.A213D | Missense Mutation (SNP) | VAF 27/121 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.783); catalogued as COSV100678824; called by muse, mutect2, varscan2
- TMX4 | c.467+1G>A p.X156_splice | Splice Site (SNP) | VAF 15/62 reads (24%) | catalogued as rs200533634; called by muse, varscan2
- TNN | c.3795C>G p.F1265L | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.342); catalogued as COSV53424730; called by muse, mutect2, varscan2
- USP15 | c.2701G>A p.D901N (on ENST00000280377 / NM_001351159.2; = p.D872N on NM_006313.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.163); catalogued as COSV54786753; called by muse, mutect2, varscan2
- USP26 | c.1937G>A p.R646Q | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.464); catalogued as rs776467655; called by muse, mutect2, varscan2
- VSTM2B | c.124G>C p.G42R | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1179195599; called by muse, mutect2, varscan2
- ZBBX | c.2068G>T p.D690Y | Missense Mutation (SNP) | VAF 34/58 reads (59%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs374795192; called by muse, mutect2, varscan2
- ZNF257 | c.1478G>C p.G493A | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.381); catalogued as COSV101448006; called by muse, mutect2, varscan2
- ZXDA | c.751G>T p.A251S | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.012); catalogued as rs1488716827, COSV62388628; called by muse, mutect2, varscan2
- AKR1D1 | c.799G>T p.G267W | Missense Mutation (SNP) | VAF 35/144 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ASIC5 | c.626C>A p.T209N | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- ASTN1 | c.2448C>A p.Y816* | Nonsense Mutation (SNP) | VAF 50/204 reads (25%) | called by muse, mutect2, varscan2
- ATP1A4 | c.155A>G p.H52R | Missense Mutation (SNP) | VAF 16/150 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, varscan2
- BAHCC1 | c.1543A>G p.K515E | Missense Mutation (SNP) | VAF 62/108 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- BLZF1 | c.97G>T p.V33F | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- BOLL | c.320C>A p.P107Q | Missense Mutation (SNP) | VAF 44/146 reads (30%) | SIFT tolerated (0.32); PolyPhen benign (0.341); called by muse, varscan2
- C6orf132 | c.2278C>G p.P760A | Missense Mutation (SNP) | VAF 19/120 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- C7 | c.1325A>T p.K442I | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- CCDC168 | c.11154T>G p.S3718R | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCL4L2 | c.280C>T p.Q94* (on ENST00000617405 / NM_001291475.2; = p.G90= on NM_001291471.2) | Nonsense Mutation (SNP) | VAF 47/427 reads (11%) | called by muse, mutect2, varscan2
- CCNF | c.1488-1G>C p.X496_splice | Splice Site (SNP) | VAF 38/152 reads (25%) | called by muse, mutect2, varscan2
- CDH8 | c.1295A>T p.H432L | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- CMYA5 | c.2965G>T p.D989Y | Missense Mutation (SNP) | VAF 30/43 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CNTN4 | c.497A>T p.Q166L | Missense Mutation (SNP) | VAF 78/112 reads (70%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- CPEB4 | c.233A>G p.E78G | Missense Mutation (SNP) | VAF 34/122 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- CPED1 | c.2211C>G p.N737K | Missense Mutation (SNP) | VAF 60/162 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.171); called by muse, varscan2
- CUX2 | c.562G>C p.G188R | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- DCTN6 | c.344G>T p.R115I | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.83); called by muse, mutect2, varscan2
- DNAH11 | c.1561A>G p.S521G | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.36); PolyPhen benign (0.258); called by muse, mutect2
- DNAJC21 | c.1213C>T p.P405S | Missense Mutation (SNP) | VAF 50/145 reads (34%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- DSCAML1 | c.349C>A p.L117I (on ENST00000321322; = p.L57I on NM_020693.4) | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- DSE | c.286G>T p.A96S | Missense Mutation (SNP) | VAF 33/98 reads (34%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- EIF4ENIF1 | c.2570T>C p.M857T | Missense Mutation (SNP) | VAF 47/159 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- EME2 | c.1084A>G p.I362V | Missense Mutation (SNP) | VAF 61/190 reads (32%) | SIFT tolerated (0.26); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- ERCC6 | c.3567_3574del p.S1189Rfs*16 | Frame Shift Del (DEL) | VAF 21/144 reads (15%) | called by mutect2, pindel
- FAM120A | c.2997A>T p.R999S | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- FARS2 | c.76G>C p.G26R | Missense Mutation (SNP) | VAF 51/95 reads (54%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FAT3 | c.3892G>T p.G1298W | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FMN2 | c.4451G>T p.G1484V | Missense Mutation (SNP) | VAF 21/119 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); called by muse, varscan2
- FSCN3 | c.1422C>A p.Y474* | Nonsense Mutation (SNP) | VAF 21/51 reads (41%) | called by muse, mutect2, varscan2
- FYB2 | c.1334dup p.T446Dfs*6 | Frame Shift Ins (INS) | VAF 10/74 reads (14%) | called by mutect2, varscan2
- GBP2 | c.149G>A p.G50D | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GBX2 | c.238C>T p.H80Y | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- GPR179 | c.5031G>T p.Q1677H (on ENST00000621958; = p.Q1676H on NM_001004334.4) | Missense Mutation (SNP) | VAF 35/291 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- GRIN2B | c.1187C>T p.P396L | Missense Mutation (SNP) | VAF 71/107 reads (66%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- H2AC14 | c.10C>G p.R4G | Missense Mutation (SNP) | VAF 10/10 reads (100%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.705); called by muse, mutect2
- H3-2 | c.223A>G p.I75V | Missense Mutation (SNP) | VAF 27/236 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- HNF4A | c.670G>T p.A224S | Missense Mutation (SNP) | VAF 13/184 reads (7%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.451); called by muse, mutect2
- HNF4A | c.1382C>A p.S461Y | Missense Mutation (SNP) | VAF 26/164 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- HOXA3 | c.152C>T p.S51F | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- HOXD1 | c.79T>C p.F27L | Missense Mutation (SNP) | VAF 35/183 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- IFNA2 | c.256A>T p.I86F | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- IGKV1-17 | c.22C>A p.Q8K | Missense Mutation (SNP) | VAF 24/252 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.076); called by muse, mutect2
- IGKV1D-17 | c.22C>A p.Q8K | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- IGLL5 | c.72G>T p.W24C | Missense Mutation (SNP) | VAF 58/189 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.778); called by muse, mutect2, varscan2
- IL26 | c.277G>T p.V93F | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.988); called by mutect2, varscan2
- INTS2 | c.2211T>A p.D737E | Missense Mutation (SNP) | VAF 79/157 reads (50%) | SIFT tolerated (0.67); PolyPhen benign (0.007); called by muse, varscan2
- IPO8 | c.2776G>T p.E926* | Nonsense Mutation (SNP) | VAF 116/269 reads (43%) | called by muse, varscan2
- ITGA6 | c.3262G>T p.D1088Y (on ENST00000442250; = p.D1049Y on NM_001079818.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); called by muse, varscan2
- KANK4 | c.2177A>T p.H726L | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- KATNIP | c.1266A>T p.R422S | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- KIF13A | c.1885G>T p.E629* | Nonsense Mutation (SNP) | VAF 52/319 reads (16%) | called by muse, mutect2, varscan2
- KIR3DL2 | c.177G>A p.M59I | Missense Mutation (SNP) | VAF 28/163 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- LAMC3 | c.2311G>T p.E771* | Nonsense Mutation (SNP) | VAF 15/31 reads (48%) | called by muse, mutect2, varscan2
- LIPF | c.473T>A p.V158E | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- LOXL3 | c.27G>C p.W9C | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); called by muse, varscan2
- LYST | c.9383T>A p.I3128N | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.377); called by muse, mutect2
- LYST | c.5947C>G p.P1983A | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- M1AP | c.1451C>G p.T484S | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.38); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MAML2 | c.1352A>T p.Q451L | Missense Mutation (SNP) | VAF 86/274 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); called by muse, mutect2, varscan2
- MCPH1 | c.238A>G p.R80G | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- MKKS | c.967C>A p.P323T | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.22); called by muse, mutect2, varscan2
- MUC17 | c.7487C>T p.S2496F | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.449); called by muse, mutect2, varscan2
- MYLK | c.33C>G p.H11Q | Missense Mutation (SNP) | VAF 42/155 reads (27%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NBR1 | c.1132G>C p.E378Q | Missense Mutation (SNP) | VAF 94/184 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, varscan2
- NRXN1 | c.4063T>A p.S1355T | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- NTN4 | c.1106A>T p.Q369L | Missense Mutation (SNP) | VAF 18/119 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.415); called by muse, mutect2, varscan2
- NUP210L | c.2803C>A p.Q935K | Missense Mutation (SNP) | VAF 29/133 reads (22%) | SIFT tolerated (0.96); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NUTM1 | c.1687T>A p.W563R | Missense Mutation (SNP) | VAF 34/51 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- OCRL | c.2404G>T p.V802F | Missense Mutation (SNP) | VAF 82/127 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- OR13C9 | c.241A>C p.T81P | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.24); called by muse, mutect2, varscan2
- OR2T1 | c.165T>G p.H55Q | Missense Mutation (SNP) | VAF 22/35 reads (63%) | SIFT deleterious (0.01); PolyPhen benign (0.323); called by muse, varscan2
- OR8J3 | c.654T>A p.Y218* | Nonsense Mutation (SNP) | VAF 12/43 reads (28%) | called by muse, mutect2, varscan2
- OVCH1 | c.1139C>A p.P380Q | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PAMR1 | c.902A>T p.N301I (on ENST00000619888 / NM_001001991.3; = p.N318I on NM_015430.4) | Missense Mutation (SNP) | VAF 27/161 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- PARD6G | c.998A>G p.Q333R | Missense Mutation (SNP) | VAF 35/99 reads (35%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PASD1 | c.943G>T p.D315Y | Missense Mutation (SNP) | VAF 104/156 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, varscan2
- PCDHA5 | c.1658T>C p.F553S | Missense Mutation (SNP) | VAF 34/143 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.314); called by muse, mutect2, varscan2
- PCDHB4 | c.1222C>A p.L408M | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- PGC | c.778G>T p.G260C | Missense Mutation (SNP) | VAF 35/135 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- PIN4 | c.413A>T p.D138V (on ENST00000664196; = p.D113V on NM_006223.4) | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- PLCB1 | c.346del p.H116Ifs*2 | Frame Shift Del (DEL) | VAF 37/133 reads (28%) | called by mutect2, pindel, varscan2
- PPFIA2 | c.1131+1G>C p.X377_splice | Splice Site (SNP) | VAF 10/95 reads (11%) | called by muse, mutect2, varscan2
- PRF1 | c.414G>T p.K138N | Missense Mutation (SNP) | VAF 41/227 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PTPRN | c.1958G>T p.R653L | Missense Mutation (SNP) | VAF 122/383 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- PTPRT | c.3766A>T p.T1256S | Missense Mutation (SNP) | VAF 45/122 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RBFOX1 | c.260G>T p.G87V | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.284); called by muse, mutect2, varscan2
- RBM20 | c.1858G>T p.D620Y | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, varscan2
- RNF216 | c.1812-3T>A | Splice Region (SNP) | VAF 12/76 reads (16%) | called by muse, mutect2, varscan2
- RPS13 | c.22G>T p.G8W | Missense Mutation (SNP) | VAF 51/143 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RYR2 | c.959A>T p.E320V | Missense Mutation (SNP) | VAF 14/133 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.761); called by muse, mutect2, varscan2
- RYR3 | c.4163A>T p.Y1388F | Missense Mutation (SNP) | VAF 46/86 reads (53%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.474); called by muse, varscan2
- SETX | c.3989C>A p.S1330Y | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.44); called by muse, mutect2, varscan2
- SHROOM3 | c.4699C>T p.P1567S | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SLC18A2 | c.1013G>A p.S338N | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- SLC35D1 | c.997A>T p.T333S | Missense Mutation (SNP) | VAF 76/224 reads (34%) | SIFT tolerated (0.69); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SLC39A12 | c.1709G>T p.G570V (on ENST00000377369 / NM_001145195.2; = p.G533V on NM_152725.3) | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC4A4 | c.2848G>T p.V950F (on ENST00000264485 / NM_001098484.3; = p.V906F on NM_003759.4) | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- SPATA31A7 | c.328G>C p.D110H | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.384); called by muse, mutect2, varscan2
- SPIDR | c.654G>C p.Q218H | Missense Mutation (SNP) | VAF 97/220 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.088); called by muse, varscan2
- STRN3 | c.1187C>T p.S396F | Missense Mutation (SNP) | VAF 35/115 reads (30%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- STXBP6 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 17/30 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- TAS2R42 | c.164C>A p.T55K | Missense Mutation (SNP) | VAF 67/103 reads (65%) | SIFT deleterious (0.05); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TBX22 | c.1433A>T p.N478I | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.401); called by muse, mutect2, varscan2
- TCEAL6 | c.502G>T p.D168Y | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- TCF23 | c.26C>A p.P9Q | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.04); called by muse, varscan2
- TMC6 | c.2414C>A p.A805D | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- TNN | c.3551A>T p.K1184M | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, varscan2
- TNNI3 | c.542C>A p.T181N | Missense Mutation (SNP) | VAF 43/189 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- TP53TG5 | c.526C>A p.Q176K | Missense Mutation (SNP) | VAF 26/144 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- TSHZ2 | c.1902C>A p.F634L | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2, varscan2
- TTC25 | c.341G>T p.R114L | Missense Mutation (SNP) | VAF 65/255 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.679); called by muse, mutect2, varscan2
- UBIAD1 | c.905G>C p.S302T | Missense Mutation (SNP) | VAF 78/248 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0.102); called by mutect2, varscan2
- UGT2B28 | c.244A>G p.T82A | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- UNC80 | c.2578G>T p.D860Y | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- USH1C | c.718C>T p.H240Y | Missense Mutation (SNP) | VAF 53/197 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- ZFHX2 | c.6444C>G p.C2148W | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZFHX3 | c.5531A>G p.Q1844R | Missense Mutation (SNP) | VAF 35/197 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- ZFHX4 | c.9024G>T p.E3008D | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- ZNF324 | c.1493A>G p.H498R | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ZNF536 | c.3234G>T p.K1078N | Missense Mutation (SNP) | VAF 40/82 reads (49%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- ZNF729 | c.763A>T p.K255* | Nonsense Mutation (SNP) | VAF 7/26 reads (27%) | called by muse, mutect2, varscan2
- ZNF85 | c.86A>G p.Y29C | Missense Mutation (SNP) | VAF 41/138 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNRF3 | c.1288G>T p.A430S (on ENST00000544604 / NM_001206998.2; = p.A330S on NM_032173.3) | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- ABCC12 | c.1770T>C p.Y590= | Silent (SNP) | VAF 37/76 reads (49%) | catalogued as rs1567451549; called by muse, mutect2, varscan2
- ADAM19 | c.309A>G p.Q103= | Silent (SNP) | VAF 18/86 reads (21%) | called by muse, varscan2
- AMER3 | c.1239A>T p.P413= | Silent (SNP) | VAF 12/32 reads (38%) | called by muse, mutect2, varscan2
- APOL3 | c.414C>T p.D138= (on ENST00000349314 / NM_145640.2; = p.D67= on NM_014349.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 31/76 reads (41%) | catalogued as rs1018256911; called by muse, mutect2, varscan2
- ATP8A2 | c.729C>T p.P243= | Silent (SNP) | VAF 12/50 reads (24%) | called by muse, mutect2, varscan2
- C12orf66 | c.864G>T p.T288= | Silent (SNP) | VAF 25/51 reads (49%) | called by muse, mutect2, varscan2
- CLCA4 | c.2223A>G p.V741= | Silent (SNP) | VAF 65/187 reads (35%) | catalogued as rs1406689110; called by muse, mutect2, varscan2
- COL6A1 | c.822G>T p.P274= | Silent (SNP) | VAF 7/60 reads (12%) | catalogued as rs886044503; called by muse, mutect2, varscan2
- DGAT1 | c.12C>T p.R4= | Silent (SNP) | VAF 16/74 reads (22%) | called by muse, mutect2, varscan2
- DNAJC21 | c.1212G>T p.L404= | Silent (SNP) | VAF 49/142 reads (35%) | called by muse, mutect2, varscan2
- DYSF | c.2451C>T p.S817= | Silent (SNP) | VAF 22/130 reads (17%) | catalogued as COSV50545209, COSV99243412; called by muse, mutect2, varscan2
- EFCAB8 | c.2004C>A p.L668= | Silent (SNP) | VAF 21/103 reads (20%) | catalogued as rs1457126866; called by muse, varscan2
- FASN | c.1512C>T p.R504= | Silent (SNP) | VAF 30/274 reads (11%) | catalogued as rs747732644, COSV60757711; called by muse, mutect2, varscan2
- FAT4 | c.1971G>T p.L657= | Silent (SNP) | VAF 11/26 reads (42%) | called by muse, mutect2, varscan2
- FHOD3 | c.2682C>T p.I894= (on ENST00000359247 / NM_001281739.3; = p.I911= on NM_025135.5) | Silent (SNP) | VAF 22/73 reads (30%) | catalogued as rs144580638, COSV57191379; called by muse, mutect2, varscan2
- FOXD4L5 | c.861C>G p.G287= | Silent (SNP) | VAF 79/313 reads (25%) | catalogued as COSV66241341; called by muse, mutect2, varscan2
- FRY | c.5844A>G p.K1948= | Silent (SNP) | VAF 6/100 reads (6%) | catalogued as COSV66573123; called by muse, mutect2
- GRIK1 | c.2046C>A p.P682= | Silent (SNP) | VAF 18/134 reads (13%) | called by muse, varscan2
- GSG1L | c.447G>A p.L149= | Silent (SNP) | VAF 14/50 reads (28%) | called by muse, mutect2, varscan2
- HCN3 | c.2115A>G p.L705= | Silent (SNP) | VAF 44/79 reads (56%) | called by muse, mutect2, varscan2
- HRNR | c.2268G>C p.G756= | Silent (SNP) | VAF 94/204 reads (46%) | catalogued as rs758697738; called by muse, mutect2, varscan2
- JCAD | c.2241C>A p.A747= | Silent (SNP) | VAF 22/89 reads (25%) | called by muse, mutect2, varscan2
- KCNV2 | c.1038C>T p.L346= | Silent (SNP) | VAF 51/240 reads (21%) | called by muse, varscan2
- KIAA0100 | c.5109C>T p.I1703= | Silent (SNP) | VAF 37/90 reads (41%) | catalogued as rs753768560; called by muse, mutect2, varscan2
- KIAA1217 | c.3102A>G p.E1034= | Silent (SNP) | VAF 4/12 reads (33%) | called by muse, mutect2, varscan2
- KIAA2012 | c.3150A>T p.L1050= | Silent (SNP) | VAF 25/135 reads (19%) | called by muse, varscan2
- KIF13A | c.1884G>C p.L628= | Silent (SNP) | VAF 51/319 reads (16%) | called by muse, mutect2, varscan2
- KRTAP5-10 | c.399C>A p.G133= | Silent (SNP) | VAF 29/88 reads (33%) | called by muse, mutect2, varscan2
- LMF2 | c.717G>T p.V239= | Silent (SNP) | VAF 27/165 reads (16%) | called by muse, mutect2, varscan2
- LRFN3 | c.1104G>T p.A368= | Silent (SNP) | VAF 49/427 reads (11%) | called by muse, mutect2, varscan2
- LY6H | c.375G>T p.G125= | Silent (SNP) | VAF 25/74 reads (34%) | catalogued as rs1329188690, COSV100713850, COSV61370677; called by muse, mutect2, varscan2
- MMP19 | c.376C>A p.R126= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as COSV59450620; called by muse, mutect2, varscan2
- MOG | c.495C>A p.L165= | Silent (SNP) | VAF 96/126 reads (76%) | called by muse, mutect2, varscan2
- NSMAF | c.501C>A p.A167= | Silent (SNP) | VAF 16/82 reads (20%) | called by muse, varscan2
- OLFML2B | c.807G>T p.L269= | Silent (SNP) | VAF 54/222 reads (24%) | catalogued as rs1413878605; called by muse, mutect2, varscan2
- OR10J3 | c.918G>C p.G306= | Silent (SNP) | VAF 13/84 reads (15%) | catalogued as COSV100171937; called by muse, mutect2, varscan2
- PIK3R6 | c.1548C>T p.D516= | Silent (SNP) | VAF 9/55 reads (16%) | catalogued as rs747980309; called by mutect2, varscan2
- PIP4K2A | c.768G>T p.L256= | Silent (SNP) | VAF 33/194 reads (17%) | called by muse, mutect2, varscan2
- POLR3K | c.4C>T p.L2= | Silent (SNP) | VAF 9/73 reads (12%) | catalogued as rs919963543; called by muse, mutect2, varscan2
- PRSS1 | c.366C>T p.R122= | Silent (SNP) | VAF 16/124 reads (13%) | catalogued as rs201487096, COSV61190827; ClinVar: benign / likely benign; called by muse, mutect2, varscan2
- PUM2 | c.1815A>T p.I605= | Silent (SNP) | VAF 68/185 reads (37%) | called by muse, mutect2, varscan2
- RCVRN | c.264C>A p.I88= | Silent (SNP) | VAF 41/162 reads (25%) | catalogued as rs1025853998; called by muse, mutect2, varscan2
- RGS1 | c.181C>T p.L61= | Silent (SNP) | VAF 13/81 reads (16%) | called by muse, mutect2, varscan2
- RIMBP3B | c.4632G>A p.E1544= | Silent (SNP) | VAF 69/385 reads (18%) | called by muse, mutect2, varscan2
- RING1 | c.1134G>A p.S378= | Silent (SNP) | VAF 57/120 reads (48%) | catalogued as rs369799440; called by muse, mutect2, varscan2
- ROBO1 | c.762C>T p.A254= | Silent (SNP) | VAF 9/55 reads (16%) | catalogued as rs762931858, COSV71392013; called by muse, mutect2, varscan2
- SCNN1G | c.261C>A p.V87= | Silent (SNP) | VAF 65/181 reads (36%) | called by muse, mutect2, varscan2
- SETBP1 | c.2307G>T p.V769= | Silent (SNP) | VAF 34/100 reads (34%) | called by muse, mutect2, varscan2
- SLC37A3 | c.1017G>T p.G339= | Silent (SNP) | VAF 11/28 reads (39%) | called by muse, mutect2
- SLC4A10 | c.39G>T p.L13= | Silent (SNP) | VAF 25/100 reads (25%) | called by muse, varscan2
- SMYD1 | c.1038C>A p.T346= | Silent (SNP) | VAF 27/80 reads (34%) | called by muse, mutect2, varscan2
- SYT3 | c.435G>C p.L145= | Silent (SNP) | VAF 5/29 reads (17%) | called by muse, mutect2, varscan2
- TCF20 | c.4368C>T p.A1456= | Silent (SNP) | VAF 8/50 reads (16%) | catalogued as rs764607943; called by muse, mutect2, varscan2
- TENT5D | c.753T>C p.C251= | Silent (SNP) | VAF 8/21 reads (38%) | called by muse, mutect2, varscan2
- TMTC1 | c.75G>A p.A25= | Silent (SNP) | VAF 28/51 reads (55%) | called by muse, mutect2, varscan2
- TSC2 | c.2937C>T p.S979= | Silent (SNP) | VAF 18/170 reads (11%) | catalogued as COSV54777609; called by muse, mutect2, varscan2
- UGT3A2 | c.231C>T p.I77= | Silent (SNP) | VAF 8/26 reads (31%) | called by muse, mutect2, varscan2
- UNC80 | c.2577G>T p.V859= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as rs904629599; called by muse, mutect2, varscan2
- UTF1 | c.297G>T p.S99= | Silent (SNP) | VAF 25/75 reads (33%) | called by muse, mutect2, varscan2
- YTHDF2 | c.765C>A p.T255= | Silent (SNP) | VAF 50/140 reads (36%) | called by muse, mutect2, varscan2
- ZNF423 | c.591G>A p.T197= (on ENST00000563137 / NM_001379286.1; = p.T189= on NM_015069.4) | Silent (SNP) | VAF 32/148 reads (22%) | catalogued as rs528007456, COSV99280302; called by muse, mutect2, varscan2
- ZNF628 | c.1641C>T p.F547= | Silent (SNP) | VAF 22/94 reads (23%) | called by muse, mutect2, varscan2
- ZNF717 | c.978C>A p.L326= | Silent (SNP) | VAF 10/24 reads (42%) | called by muse, mutect2, varscan2
- AC023469.1 | n.186T>A | RNA (SNP) | VAF 33/201 reads (16%) | called by muse, mutect2, varscan2
- ACBD5 | chr10:27196602 A>T | 3'Flank (SNP) | VAF 7/23 reads (30%) | called by muse, mutect2
- ADGRA1 | c.4-3823C>A | Intron (SNP) | VAF 51/226 reads (23%) | called by muse, mutect2, varscan2
- ANO1 | c.897+15C>A | Intron (SNP) | VAF 36/122 reads (30%) | called by muse, mutect2, varscan2
- AP000769.5 | chr11:65500262 G>A | 5'Flank (SNP) | VAF 18/179 reads (10%) | called by muse, mutect2
- AP3B2 | c.1056-21T>C | Intron (SNP) | VAF 44/78 reads (56%) | catalogued as rs769941994; called by muse, mutect2, varscan2
- ATRNL1 | c.3795+48191del | Intron (DEL) | VAF 7/71 reads (10%) | called by pindel, varscan2
- ATRNL1 | c.3795+48200T>C | Intron (SNP) | VAF 8/84 reads (10%) | catalogued as rs1275438888; called by muse, varscan2
- CCT3 | c.31+1001A>G | Intron (SNP) | VAF 12/128 reads (9%) | catalogued as rs1291738365; called by muse, mutect2
- CNOT2 | c.48+15821A>G | Intron (SNP) | VAF 36/99 reads (36%) | called by muse, mutect2, varscan2
- CSMD2 | c.1326+5914C>A | Intron (SNP) | VAF 28/163 reads (17%) | called by muse, mutect2, varscan2
- CTSA | c.358-22C>G | Intron (SNP) | VAF 54/154 reads (35%) | called by muse, varscan2
- CXCR2P1 | n.1039A>T | RNA (SNP) | VAF 11/52 reads (21%) | called by muse, mutect2, varscan2
- DCHS2 | n.7779C>T | RNA (SNP) | VAF 12/66 reads (18%) | called by mutect2, varscan2
- DNAH14 | c.9206-2463G>T | Intron (SNP) | VAF 21/188 reads (11%) | called by muse, mutect2, varscan2
- DNMT1 | c.2070-28G>A | Intron (SNP) | VAF 23/135 reads (17%) | called by muse, mutect2, varscan2
- DST | c.4297-4526A>G | Intron (SNP) | VAF 32/174 reads (18%) | catalogued as rs1181231388; called by muse, varscan2
- DUSP15 | c.-21G>A | 5'UTR (SNP) | VAF 4/16 reads (25%) | catalogued as rs1213234456, COSV99639667; called by mutect2, varscan2
- EFCAB1 | c.-3G>T | 5'UTR (SNP) | VAF 9/78 reads (12%) | catalogued as COSV50617806; called by muse, mutect2, varscan2
- FARP2 | c.1411+703del | Intron (DEL) | VAF 36/92 reads (39%) | called by mutect2, pindel*, varscan2
- FMO9P | n.471C>G | RNA (SNP) | VAF 9/44 reads (20%) | called by muse, varscan2
- FOXP4 | c.204+4357A>G | Intron (SNP) | VAF 12/154 reads (8%) | called by muse, mutect2
- GREB1L | c.2182+49C>A | Intron (SNP) | VAF 9/61 reads (15%) | called by muse, varscan2
- HBE1 | c.-267+102281G>T | Intron (SNP) | VAF 14/39 reads (36%) | called by muse, mutect2
- HBE1 | c.-267+102279T>G | Intron (SNP) | VAF 12/36 reads (33%) | called by muse, mutect2
- HIRA | c.-22C>A | 5'UTR (SNP) | VAF 74/208 reads (36%) | catalogued as COSV99600971; called by muse, varscan2
- HNRNPA3P1 | n.327A>T | RNA (SNP) | VAF 5/25 reads (20%) | called by muse, mutect2
- HYDIN | c.-23-16902T>A | Intron (SNP) | VAF 5/56 reads (9%) | catalogued as rs1307561024; called by muse, mutect2
- IGFN1 | c.1242-1822G>T | Intron (SNP) | VAF 51/192 reads (27%) | catalogued as rs540272590; called by muse, mutect2, varscan2
- LIG1 | c.*33A>G | 3'UTR (SNP) | VAF 14/35 reads (40%) | catalogued as rs1309747622; called by muse, mutect2, varscan2
- LINC02035 | n.86T>C | RNA (SNP) | VAF 8/50 reads (16%) | called by mutect2, varscan2
- MACF1 | c.220+18306C>T | Intron (SNP) | VAF 16/38 reads (42%) | called by muse, varscan2
- NETO1 | c.29-337C>A | Intron (SNP) | VAF 45/96 reads (47%) | called by muse, mutect2, varscan2
- NSMCE4A | c.845-507A>G | Intron (SNP) | VAF 4/45 reads (9%) | called by muse, varscan2
- PATJ | c.*1975C>G | 3'UTR (SNP) | VAF 6/36 reads (17%) | catalogued as rs1178016157; called by mutect2, varscan2
- PIGG | c.-7G>T | 5'UTR (SNP) | VAF 42/238 reads (18%) | called by muse, mutect2, varscan2
- PNCK | c.539-36T>A | Intron (SNP) | VAF 86/129 reads (67%) | called by muse, mutect2, varscan2
- RHOC | c.-89C>A | 5'UTR (SNP) | VAF 59/160 reads (37%) | catalogued as rs1478172959; called by muse, mutect2, varscan2
- RPL23AP42 | n.138C>A | RNA (SNP) | VAF 15/130 reads (12%) | called by muse, mutect2, varscan2
- SLC16A7 | c.217+15061G>C | Intron (SNP) | VAF 36/74 reads (49%) | called by muse, mutect2, varscan2
- SLC25A41 | c.364-427C>T | Intron (SNP) | VAF 4/18 reads (22%) | catalogued as rs1360998130; called by mutect2, varscan2
- SLC4A10 | c.49-62216T>C | Intron (SNP) | VAF 24/64 reads (38%) | called by muse, mutect2, varscan2
- SLMAP | c.1135+6942C>T | Intron (SNP) | VAF 20/87 reads (23%) | catalogued as rs777858277; called by muse, mutect2, varscan2
- SQLE | c.-776C>T | 5'UTR (SNP) | VAF 58/218 reads (27%) | called by muse, mutect2, varscan2
- TGFBR3 | c.*1417C>T | 3'UTR (SNP) | VAF 19/53 reads (36%) | called by muse, varscan2
- TMEM270 | c.72+210G>T | Intron (SNP) | VAF 15/30 reads (50%) | catalogued as rs1554639248; called by muse, mutect2, varscan2
- TMTC1 | c.1785+27del | Intron (DEL) | VAF 6/32 reads (19%) | catalogued as rs376468800; called by pindel, varscan2
- TPST2 | c.-160-10582A>G | Intron (SNP) | VAF 45/133 reads (34%) | called by muse, mutect2, varscan2
- TTLL7 | c.-229G>C | 5'UTR (SNP) | VAF 37/74 reads (50%) | called by muse, mutect2, varscan2
- UGT2A3 | c.864+1939C>A | Intron (SNP) | VAF 15/67 reads (22%) | called by muse, mutect2, varscan2
- UNC5A | c.293-2483del | Intron (DEL) | VAF 17/57 reads (30%) | called by mutect2, pindel, varscan2
- USP6 | c.156-115G>T | Intron (SNP) | VAF 32/52 reads (62%) | called by muse, mutect2, varscan2
- ZMYM2 | c.-57-4778G>T | Intron (SNP) | VAF 33/114 reads (29%) | called by muse, mutect2, varscan2
- ZNF99 | c.-38C>A | 5'UTR (SNP) | VAF 9/33 reads (27%) | called by muse, mutect2
